Gene-level copy-number profile of tumor specimen C3N-02786-02 from CPTAC case C3N-02786, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 40.0 years (14,593 days).
Specimen C3N-02786-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 858cd1c6-8ca4-4dd9-82fd-42bf590a90d4.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-02786-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,218 have no estimate.
https://portal.gdc.cancer.gov/files/45b14d14-fa9c-431b-8dae-7873b63516eb

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 6; copy number 1: 101; copy number 2: 25,896; copy number 3: 419; copy number 4: 30,049; copy number 5: 334; copy number 6: 1,589; copy number 7: 1; copy number 8: 10.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:12,822,686–12,831,410, 2 genes: LINC01784, PRAMEF11.
- chr1:12,916,610–12,920,482, 1 gene (within-gene range 0–1): PRAMEF7.
- chr19:57,454,790–57,477,570, 3 genes (within-gene range 0–2): VN1R1, VN1R107P, ZNF772.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 98. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
